Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5440, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5440-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

Collected:

Received:

Case type: Surgical Case

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) TOTAL LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTION:
INVASIVE SQUAMOUS CELL CARCINOMA MODERATELY TO POORLY DIFFERENTIATED (8.5 CM).
TUMOR INVOLVES THE LEFT PYRIFORM SINUS AND EXTENDS THROUGH THE THYROID CARTILAGE
INTO THE ANTERIOR SOFT TISSUE.
PERINEURAL AND LYMPHOVASCULAR INVASION IS IDENTIFIED.
Margins of resection are free of tumor.
Five right neck lymph nodes, negative for tumor.
FIVE OF FORTY-TWO LEFT NECK LYMPH NODES POSITIVE FOR TUMOR (FIVE LYMPH NODES WERE IN
LEVEL 3.
EXTRANODAL EXTENSION OF TUMOR IS PRESENT.

GROSS DESCRIPTION

(A) TOTAL LARYNGOPHARYNGECTOMY, BILATERAL NECK DISSECTION - A product of total laryngopharyngectomy and bilateral neck dissection with overall measurements of the laryngopharyngectomy without the dissection, 7.0 x 8.5 x 4.5 cm and ulcerated excavating tumor mass involves entirely the left pyriform sinus and extending into the anterior soft tissue and involving the thyroid cartilage, measuring 4.5 x 3.5 x 8.0 cm. The mucosal and soft tissue margin are grossly free of any involvement. The tumor impinges medially on the supraglottic region but does not involve the overlying mucosa. Separate tumor nodules were also noted in the anterior soft tissue component of the tumor. The nodules measure 1.0 cm in diameter. The specimen is submitted as follows:

SECTION CODE: A1-A10, margin submitted for frozen section; A11, A12, representative section of the left thyroid lobe; A13, transglottic mucosa; A14, transglottic mucosa left; A15-A30, representative section of the tumor and adjacent mucosa from right to left.

The right neck dissection was divided by the surgeons in regions 2, 3, and 4.

Level 2 measuring (5.0 x 4.0 x 1.5 cm). Identified are nineteen lymph nodes ranging in size (0.3 x 0.2 x 0.2 to 2.5 x 1.0 x 0.5 cm).

Level 3 measuring (4.0 x 3.0 x 0.6 cm). Identified are ten lymph nodes ranging in size (0.2 x 0.2 x 0.2 to 2.5 x 0.8 x 0.4 cm).

Level 4 measuring (3.5 x 2.5 x 0.6 cm). Identified are nine lymph nodes ranging in size (0.2 x 0.2 x 0.2 to 0.8 x 0.4 x 0.4 cm).

Left neck dissection divided by the surgeon in levels 2, 3, and 4.

Left neck Level 2 measuring (5.5 x 3.0 x 1.0 cm). Identified are fifteen lymph nodes ranging in size (0.2 x 0.2 x 0.2 to 1.5 x 0.8 x 0.4 cm).

Level 3 measuring (5.0 x 3.0 x 2.0 cm). Identified are nine lymph nodes ranging in size (0.3 x 0.3 x 0.3 to 2.5 x 2.0 x 2.0 cm). The largest lymph node is grossly positive.

Level 4 measuring (6.0 x 3.0 x 1.0 cm). Identified are nine lymph nodes ranging in size (0.3 x 0.2 x 0.2 to 0.8 x 0.5 x 0.3 cm).

[page 2 of 3]
Surgical Pathology Report

Collected
Received

Pathologist:
Case type: Surgical Case

SECTION CODE: Right neck level 2; A31, four lymph nodes; A32, four lymph nodes; A33, four lymph nodes; A34, four lymph nodes; A35, two lymph nodes; A36, one lymph node bisected; A37, one lymph node bisected; A38, one lymph node bisected; A39, one lymph node bisected; A40, one lymph node. Right neck level 3; A41, three lymph nodes; A42, two lymph nodes; A43, five lymph nodes; right neck level 4 A44, four lymph nodes; A45, three lymph nodes; A46, two lymph nodes; Left neck level 2; A47, one lymph node bisected-grossly positive; A48, one lymph node bisected grossly positive; A49, one lymph node; A50, one lymph node bisected; A51, two lymph nodes; A52, two lymph nodes; A53, one lymph node trisected-grossly positive; A54, six lymph nodes; Left neck level 3 A55, four lymph nodes; A56, four lymph nodes; A57-A58, representative sections of the largest lymph node; Left neck level 4; A59, three lymph nodes; A60, three lymph nodes; A61, one lymph node bisected; A62, one lymph node bisected; A63-A65, one lymph node serially sectioned

*FS/DX: MARGINS FREE OF TUMOR. A6 IS A CONTAMINANT.

CLINICAL HISTORY

None given.

SNOMED CODES

[page 3 of 3]
[REDACTED]

[REDACTED]

Surgical Pathology Report

[REDACTED]

[REDACTED]

Collected: [REDACTED] Pathologist: [REDACTED]

Received: [REDACTED] Case type: Surgical Case

[REDACTED]

ADDENDUM

DIAGNOSIS

(A) TOTAL LARYNGOPHARYNGECTOMY AND BILATERAL NECK DISSECTION:
POORLY-DIFFERENTIATED SQUAMOUS CARCINOMA INVADING THYROID CARTILAGE.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file d1bff47b-6968-4204-b9b5-085d887a7100 (TCGA-CV-5440.405B31E5-CC6F-4BD4-A3CF-0E4EAAFAC4C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).